Somatic mutation profile of tumor specimen TARGET-10-PARDLJ-09A (aliquot TARGET-10-PARDLJ-09A-01D) from TARGET case TARGET-10-PARDLJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.9 years (5,446 days).
Specimen TARGET-10-PARDLJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a5a3b03-45a7-40ee-882a-76ef8cadcb7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDLJ-10A (Blood Derived Normal), aliquot TARGET-10-PARDLJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb8e8d7a-ce58-4a8e-9679-6e2f83a397f4

The open-access MAF lists 18 somatic variants for this specimen: 16 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Frame Shift Ins 2, Nonsense Mutation 1, RNA 1, Frame Shift Del 1, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 18/45 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CASKIN1 | c.2275G>A p.V759M | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as rs750979771, COSV58217487; called by muse, mutect2, varscan2
- DOCK9 | c.2660C>T p.A887V (on ENST00000376460 / NM_001366676.2; = p.A888V on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as rs375543731; called by muse, mutect2, varscan2
- PAX5 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63905581; called by muse, mutect2, varscan2
- SLC5A8 | c.1574G>A p.S525N | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV73310474; called by muse, mutect2, varscan2
- UVRAG | c.1379A>G p.H460R | Missense Mutation (SNP) | VAF 72/125 reads (58%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.69); catalogued as rs560281072; called by muse, mutect2, varscan2
- XBP1 | c.454-2A>G p.X152_splice | Splice Site (SNP) | VAF 10/13 reads (77%) | catalogued as COSV53274455; called by muse, mutect2
- CDC42BPA | c.2299C>T p.R767* | Nonsense Mutation (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- CNTNAP3 | c.1757C>T p.S586F | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FBXO45 | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- GLIPR1 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LPCAT3 | c.605A>G p.Q202R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NFKBIE | c.1479dup p.K494Efs*101 (on ENST00000275015; = p.K355Efs*101 on NM_004556.3) | Frame Shift Ins (INS) | VAF 63/150 reads (42%) | called by mutect2, pindel, varscan2
- OR1L1 | c.479_480del p.T160Rfs*11 (on ENST00000373686; = p.T110Rfs*11 on NM_001005236.3) | Frame Shift Del (DEL) | VAF 39/120 reads (33%) | called by pindel, varscan2
- PAX5 | c.332C>A p.A111D | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TCERG1 | c.2870dup p.R958Efs*5 | Frame Shift Ins (INS) | VAF 28/52 reads (54%) | called by mutect2, varscan2
- RBMX | c.372A>G p.S124= | Silent (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- BTN2A3P | n.1902C>T | RNA (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2
